TCGA case TCGA-A6-5661 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4beee9d4-ee52-4fed-bcc4-d300f5ddd4d0

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 80 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.2; Tissue or organ of origin: Ascending colon; Site of resection or biopsy: Ascending colon; Classification of tumor: primary; Age at diagnosis: 80.6 years (29,446 days); Year of diagnosis: 2010; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,020 days (2.8 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 21; Lymphatic invasion present: No; Non nodal tumor deposits: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 306 days; Disease response: Tumor Free.
- Days to follow up: 1,020 days (2.8 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 4.1 ng/mL.
- MLH1 (IHC): Loss of Expression.
- MSH2 (IHC): Normal.
- MSH6 (IHC): Normal.
- PMS2 (IHC): Loss of Expression.
- Microsatellite Instability: Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 69.1 kg; Height: 170 cm; BMI: 23.9.
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relatives with cancer history count: 2.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A6-5661-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-A6-5661-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 64; Percent normal cells: 20; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 13.
  Slide TCGA-A6-5661-01A-01-TS1: Section location: Top; Percent tumor cells: 83; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 17; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
- Sample TCGA-A6-5661-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TCGA-A6-5661-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A6-5661-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-A6-5661-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.6; Intermediate dimension: 0.8; Shortest dimension: 0.8.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 4.1; Lymphovascular invasion indicator: No; Microsatellite instability: Yes; Loci tested count: 5; Loci abnormal count: 5; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Colon polyps at procurement indicator: Yes; Mismatch rep proteins tested by IHC: Yes.
- Loss expression of mismatch repair proteins by ihc results: Mismatch rep proteins loss IHC: MLH1-Not Expressed; Mismatch rep proteins loss IHC: MSH2-Expressed; Mismatch rep proteins loss IHC: PMS2-Not Expressed; Mismatch rep proteins loss IHC: MSH6-Expressed.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,020 days; disease-specific survival: no event (censored), 1,020 days; disease-free interval: no event (censored), 1,020 days; progression-free interval: no event (censored), 1,020 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A6-5661-01A-01D-1649-01): tumor purity 0.66, ploidy 2.02, whole-genome doublings 0.
